Gene-level copy-number profile of tumor specimen C3L-03405-01 from CPTAC case C3L-03405, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.2 years (21,614 days).
Specimen C3L-03405-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0bc70e09-1157-4af2-a045-1ac10f34c997.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03405-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/f6874f28-faad-4e4b-b046-7d96f396a37f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 3; copy number 2: 7,278; copy number 3: 123; copy number 4: 43,139; copy number 5: 1,726; copy number 6: 6,492; copy number 7: 28; copy number 8: 3; copy number 11: 3; copy number 15: 4; copy number 22: 1; copy number 23: 26; copy number 32: 4; copy number 42: 4; copy number 48: 3; copy number 56: 4; copy number 62: 2; copy number 190: 8; copy number 194: 20; copy number 329: 10; copy number 340: 3; copy number 353: 5; copy number 357: 10; copy number 362: 5; copy number 380: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 114 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,752,250–55,255,635, 7 genes, copy number 362–380: SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1.
- chr9:65,189,995–65,230,861, 3 genes, copy number 11: BMS1P12, AL512605.1, AL512605.2.
- chr12:57,674,665–57,846,729, 20 genes, copy number 194 (within-gene range 4–194): RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2.
- chr12:65,758,020–68,234,686, 45 genes, copy number 15–353: RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26.
- chr12:68,746,125–68,971,570, 10 genes, copy number 357: SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:69,585,426–69,699,476, 3 genes, copy number 23 (within-gene range 3–23): CCT2, LRRC10, BEST3.
- chr12:69,713,633–70,920,738, 18 genes, copy number 48–340: AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA.
- chr17:39,063,313–39,154,394, 1 gene, copy number 190 (within-gene range 4–190): PLXDC1.
- chr17:39,156,894–39,250,818, 7 genes, copy number 190: ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
